Gene-level copy-number profile of tumor specimen ALCH-B3AU-TTP1-A from ALCHEMIST case ALCH-B3AU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 52.0 years (18,980 days).
Specimen ALCH-B3AU-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6fc5443c-4cb5-4b38-871c-986b4c2c5479.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3AU-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/ea0d6b3d-c1be-4a1a-80c2-aa895cac3ebd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 82; copy number 1: 1,597; copy number 2: 56,327; copy number 3: 228; copy number 4: 82; copy number 5: 28; copy number 6: 49; copy number 7: 1; copy number 10: 1.

Homozygous deletions (total copy number 0; autosomes only): 81 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:62,189,131–62,212,328, 5 genes: PIGPP2, RPS15AP7, L1TD1, AL162739.1, Y_RNA.
- chr1:243,056,307–243,101,744, 2 genes (within-gene range 0–2): LINC01347, RNU6-747P.
- chr4:8,949,630–8,963,981, 2 genes: AC073648.1, UNC93B8.
- chr5:160,195,744–160,204,826, 1 gene (within-gene range 0–2): FABP6-AS1.
- chr7:32,951,426–33,006,930, 3 genes: AC083863.1, FKBP9, RNU6-388P.
- chr7:51,382,284–51,389,114, 3 genes: CICP17, AC012441.2, AC012441.1.
- chr7:55,731,100–55,773,288, 6 genes: Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1.
- chr8:69,922,751–70,071,693, 6 genes: RN7SL675P, RNA5SP270, AC090574.1, SDCBPP2, SUMO2P20, PRDM14.
- chr9:112,169,286–112,173,971, 2 genes (within-gene range 0–2): Y_RNA, AL158824.1.
- chr10:50,695,592–50,708,906, 2 genes: AL589794.1, CTSLP4.
- chr11:2,159,779–2,161,221, 1 gene (within-gene range 0–2): INS.
- chr11:2,173,063–2,173,138, 1 gene: MIR4686.
- chr11:68,312,591–68,449,275, 1 gene: LRP5.
- chr12:37,575,587–37,576,384, 1 gene: ZNF970P.
- chr13:112,313,467–112,331,225, 2 genes: LINC01043, LINC01044.
- chr15:67,819,704–67,834,582, 1 gene (within-gene range 0–2): SKOR1.
- chr16:46,469,341–46,851,254, 17 genes: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2.
- chr16:81,081,945–81,096,395, 1 gene (within-gene range 0–2): GCSH.
- chr16:81,106,533–81,106,639, 1 gene (within-gene range 0–2): RNU6-1191P.
- chr17:2,712,309–2,749,504, 5 genes (within-gene range 0–2): AC005696.1, AC005696.4, CCDC92B, MIR1253, hsa-mir-1253.
- chr17:22,221,221–22,424,731, 8 genes: FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1, FLJ36000, AC132825.3.
- chr17:30,702,504–30,702,775, 1 gene: RN7SL316P.
- chr19:16,479,061–16,496,167, 1 gene (within-gene range 0–2): CALR3.
- chr19:35,785,697–35,813,299, 2 genes (within-gene range 0–2): LINC01529, PRODH2.
- chr21:44,285,838–44,330,221, 3 genes (within-gene range 0–2): AIRE, PFKL, AP001062.3.
- chr22:49,773,283–49,827,512, 3 genes: BRD1, Z98885.3, Z98885.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 79 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,632,568–2,636,620, 1 gene, copy number 5 (within-gene range 2–5): MMEL1-AS1.
- chr2:242,175,181–242,175,634, 1 gene, copy number 10: RPL23AP88.
- chr3:13,937,273–15,859,771, 49 genes, copy number 6 (within-gene range 4–6): TPRXL, AC090004.2, VN1R21P, CHCHD4, TMEM43, AC090004.1, XPC-AS1, XPC, LSM3, AC093496.1, LINC01267, RNA5SP124, SLC6A6, GRIP2, RNU6-905P, RHBDF1P1, AC090952.1, CCDC174, C3orf20, AC090957.1, LINC02011, FGD5, FGD5-AS1, NR2C2, MRPS25, RBSN, AC090954.1, RPS3AP53, COL6A4P1, CAPN7, SH3BP5-AS1, SH3BP5, RNU6-454P, HMGN2P7, METTL6, EAF1, RNU6-1024P, EAF1-AS1, COLQ, MIR4270, AC027129.1, RN7SL110P, HACL1, BTD, ANKRD28, MIR3134, AC090950.2, AC090950.1, RN7SL4P.
- chr16:32,600,299–32,615,639, 1 gene, copy number 7: AC137800.1.
- chr19:41,521,043–41,930,150, 27 genes, copy number 5: PLEKHA3P1, AC243960.3, LINC01480, AC243960.1, CEACAM21, AC243960.10, CEACAMP3, DNAJC19P2, CEACAM4, DNAJC19P3, AC243960.5, AC243960.4, CEACAM7, CEACAM5, AC243967.1, CEACAM6, AC243967.2, CEACAM3, HNRNPA1P52, AC243967.3, LYPD4, DMRTC2, RPS19, MIR6797, CD79A, ARHGEF1, ERFL.

Autosomal genes at a single copy (total copy number 1): 1,579. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
